Somatic mutation profile of tumor specimen TCGA-A2-A0YI-01A (aliquot TCGA-A2-A0YI-01A-31D-A10M-09) from TCGA case TCGA-A2-A0YI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.9 years (22,961 days).
Specimen TCGA-A2-A0YI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05e7f661-153f-4eec-bc20-a457b777e4ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0YI-10A (Blood Derived Normal), aliquot TCGA-A2-A0YI-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8589d723-9790-4596-a3bb-83392e916f34

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2836C>T p.R946W | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs746903524, COSV62571997; called by muse, mutect2, varscan2
- CLIP1 | c.1653G>C p.E551D (on ENST00000620786 / NM_001247997.1; = p.E540D on NM_002956.2) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100212048; called by muse, mutect2, varscan2
- MAP2K5 | c.322+1G>C p.X108_splice | Splice Site (SNP) | VAF 39/171 reads (23%) | catalogued as COSV51609937; called by muse, mutect2, varscan2
- MIA2 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV54488469, COSV54497533; called by muse, mutect2, varscan2
- RASGEF1C | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs777033115, COSV63177372; called by muse, mutect2, varscan2
- SIPA1L3 | c.3985C>T p.P1329S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV55908644; called by muse, mutect2, varscan2
- TRAJ21 | c.44A>G p.N15S | Missense Mutation (SNP) | VAF 33/174 reads (19%) | catalogued as rs1234242876; called by muse, mutect2, varscan2
- TRPC5 | c.426C>A p.D142E | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV53283777; called by muse, mutect2, varscan2
- ZNFX1 | c.2131C>A p.L711I | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.796); catalogued as COSV65573607; called by muse, mutect2, varscan2
- SNUPN | c.-5-19_24del | Splice Site (DEL) | VAF 16/94 reads (17%) | called by mutect2, pindel
- MEFV | c.223C>A p.R75= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1042945356, COSV54818489; called by muse, mutect2, varscan2
- MIA2 | c.1521T>A p.V507= | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as COSV54488433; called by muse, mutect2, varscan2
- SCN9A | c.3546G>A p.R1182= (on ENST00000303354; = p.R1171= on NM_002977.3) | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as COSV57600088; called by muse, mutect2, varscan2
- TBC1D32 | c.2820A>G p.K940= | Silent (SNP) | VAF 11/240 reads (5%) | catalogued as COSV99250748; called by muse, mutect2
- THSD7A | c.2358G>A p.S786= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs756443010, COSV70260098; called by mutect2, varscan2
